Gene-level copy-number profile of tumor specimen TCGA-EB-A57M-01A from TCGA case TCGA-EB-A57M, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 56.7 years (20,698 days).
Specimen TCGA-EB-A57M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.12dabbc9-8037-4fdd-b72d-a311ce5edc1d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A57M-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2a9862d2-096f-423a-9095-5da66622efe9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 4,816; copy number 2: 15,828; copy number 3: 29,444; copy number 4: 7,429; copy number 5: 1,677; copy number 6: 198; copy number 7: 110; copy number 8: 22; copy number 9: 15; copy number 10: 87; copy number 11: 23; copy number 12: 39; copy number 13: 51; copy number 18: 3; copy number 20: 21; copy number 24: 26; copy number 32: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A57M-01A-51D-A30W-01): tumor purity 0.66, ploidy 2.19, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:37,921,939–38,226,897, 4 genes: TMCO5A, LINC02345, LINC01852, AC087473.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 419 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:54,603,211–62,292,337, 107 genes, copy number 7–13 (broad region; genes not listed).
- chr6:65,788,417–66,094,909, 3 genes, copy number 7: SLC25A51P1, ADH5P4, NUFIP1P1.
- chr11:72,685,069–72,793,599, 1 gene, copy number 7 (within-gene range 5–7): ARAP1.
- chr11:72,754,729–85,627,922, 244 genes, copy number 7–20 (within-gene range 1–29) (broad region; genes not listed).
- chr11:88,504,576–89,065,945, 2 genes, copy number 10 (within-gene range 1–10): GRM5, RNU6-16P.
- chr11:100,666,459–103,895,271, 61 genes, copy number 7–32 (broad region; genes not listed).
- chr11:103,945,548–103,946,546, 1 gene, copy number 10: AP003043.1.

Autosomal genes at a single copy (total copy number 1): 4,704. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
